Somatic mutation profile of tumor specimen MMRF_1462_2_BM_CD138pos (aliquot MMRF_1462_2_BM_CD138pos_T1_KBS5U_L05840) from MMRF case MMRF_1462, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,779 days).
Specimen MMRF_1462_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 338c37cf-b00f-4803-86f2-41599a26af86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1462_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1462_1_PB_Whole_C3_KAS5U_L02464; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/072a2e67-0f26-4999-b369-ab773241fc71

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH3B1 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.102); called by muse, mutect2
- H1-10 | c.-46G>A | 5'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
